Somatic mutation profile of tumor specimen 3946a96c-e0ae-442f-83b4-a9350e (aliquot 3946a96c-e0ae-442f-83b4-a9350e_D6) from CPTAC case 17OV019, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB.
Specimen 3946a96c-e0ae-442f-83b4-a9350e: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5688918-0fb6-4af9-ba7f-e2eca818937d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 02ac4d5b-a5e7-4e2c-8ede-f752fc (Blood Derived Normal), aliquot 02ac4d5b-a5e7-4e2c-8ede-f752fc_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02df402d-6d5c-45ac-8145-8b1992261d4f

The open-access MAF lists 54 somatic variants for this specimen: 31 protein-altering or splice-affecting, 12 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 12, Intron 4, Nonsense Mutation 4, 5'Flank 3, RNA 2, Frame Shift Del 2, Splice Region 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 134/357 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen possibly damaging (0.719); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CEP120 | c.2950G>T p.A984S | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); catalogued as COSV100070875; called by muse, mutect2
- DIP2C | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 21/177 reads (12%) | catalogued as COSV55149614; called by muse, mutect2, varscan2
- GALNT11 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753195277, COSV57428210; called by muse, mutect2, varscan2
- GJD2 | c.536C>G p.S179* | Nonsense Mutation (SNP) | VAF 68/521 reads (13%) | catalogued as COSV99290686; called by muse, mutect2, varscan2
- HDGFL1 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 22/194 reads (11%) | catalogued as rs1251266103; called by muse, varscan2
- INPP5K | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs200171094; called by muse, mutect2, varscan2
- LASP1 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs758729512; called by muse, mutect2
- LOXL1 | c.647C>A p.A216E | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV56095692; called by muse, mutect2
- NPBWR1 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 18/578 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.811); catalogued as rs1484514751; called by muse, mutect2
- PARP3 | c.920C>T p.T307M | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs774210062, COSV51756050; called by muse, mutect2, varscan2
- PRKCD | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs1193871271; called by muse, mutect2, varscan2
- SMC5 | c.3277C>A p.R1093S | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.268); catalogued as COSV63192712; called by muse, mutect2
- SNX27 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100919115; called by muse, mutect2, varscan2
- TRIM43B | c.328C>A p.L110I | Missense Mutation (SNP) | VAF 152/595 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); catalogued as rs1173254528; called by muse, mutect2, varscan2
- ZBTB5 | c.1832G>C p.R611P | Missense Mutation (SNP) | VAF 174/698 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100312759; called by muse, mutect2, varscan2
- ZDBF2 | c.1155A>C p.L385F | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV65625821; called by muse, mutect2
- ZNF292 | c.2131G>A p.A711T | Missense Mutation (SNP) | VAF 32/266 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770016827; called by muse, mutect2, varscan2
- ADAMTS17 | c.2950-6C>G | Splice Region (SNP) | VAF 53/396 reads (13%) | called by muse, mutect2, varscan2
- C6orf62 | c.310G>T p.V104L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.115); called by muse, varscan2
- CELSR3 | c.1091T>G p.L364R | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- CNOT6L | c.708_709del p.I236Mfs*24 (on ENST00000504123 / NM_001286790.2; = p.I231Mfs*24 on NM_144571.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 41/134 reads (31%) | called by mutect2, pindel, varscan2
- CNTLN | c.1553del p.P518Qfs*14 | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | called by mutect2, pindel, varscan2
- DGKG | c.1340A>G p.Q447R | Missense Mutation (SNP) | VAF 96/369 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRAS1 | c.9443C>A p.A3148D | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HDAC7 | c.2326G>T p.A776S (on ENST00000427332; = p.A815S on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.335); called by muse, mutect2
- PHYKPL | c.883G>A p.V295M | Missense Mutation (SNP) | VAF 30/271 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2
- PRR23A | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 92/249 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- TDRD5 | c.2900G>T p.R967M | Missense Mutation (SNP) | VAF 40/377 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- TRMT12 | c.875G>T p.G292V | Missense Mutation (SNP) | VAF 119/381 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF404 | c.987C>A p.C329* | Nonsense Mutation (SNP) | VAF 39/299 reads (13%) | called by muse, mutect2, varscan2
- AGBL4 | c.429G>A p.R143= | Silent (SNP) | VAF 35/313 reads (11%) | catalogued as rs1453967040; called by muse, mutect2, varscan2
- CASZ1 | c.291C>T p.S97= | Silent (SNP) | VAF 42/310 reads (14%) | catalogued as rs764956311; called by muse, mutect2, varscan2
- CDK11A | c.1557A>G p.K519= (on ENST00000378633 / NM_001313896.2; = p.K516= on NM_024011.4) | Silent (SNP) | VAF 59/279 reads (21%) | called by muse, mutect2, varscan2
- CLPTM1 | c.1602G>A p.K534= | Silent (SNP) | VAF 20/244 reads (8%) | called by muse, mutect2
- IQCA1 | c.2325G>T p.A775= | Silent (SNP) | VAF 61/515 reads (12%) | catalogued as COSV54501773; called by muse, mutect2, varscan2
- KCNMA1 | c.3228T>C p.I1076= (on ENST00000286628 / NM_001161352.2; = p.I1018= on NM_002247.4) | Silent (SNP) | VAF 65/603 reads (11%) | called by muse, mutect2, varscan2
- NETO1 | c.213C>T p.I71= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV55007760; called by muse, mutect2, varscan2
- OR10G7 | c.481T>C p.L161= | Silent (SNP) | VAF 76/836 reads (9%) | catalogued as rs778661823; called by muse, mutect2
- PDZD2 | c.7752G>A p.A2584= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as rs573949489; called by muse, mutect2
- PGGHG | c.333C>G p.P111= | Silent (SNP) | VAF 38/642 reads (6%) | catalogued as rs1564839277; called by muse, mutect2
- PRICKLE1 | c.480G>A p.T160= | Silent (SNP) | VAF 104/304 reads (34%) | catalogued as rs376385820; ClinVar: likely benign; called by muse, mutect2, varscan2
- TFAP4 | c.993G>A p.P331= | Silent (SNP) | VAF 25/194 reads (13%) | catalogued as rs558262049; called by muse, mutect2, varscan2
- DAND5 | c.324+519G>A | Intron (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- ERVV-1 | chr19:53009777 C>A | 5'Flank (SNP) | VAF 35/302 reads (12%) | called by muse, mutect2, varscan2
- FAM157A | n.379C>T | RNA (SNP) | VAF 14/252 reads (6%) | called by muse, mutect2
- HSD3B7 | c.166+51C>A | Intron (SNP) | VAF 19/167 reads (11%) | called by muse, mutect2, varscan2
- KRT8P11 | n.177G>T | RNA (SNP) | VAF 78/490 reads (16%) | called by muse, mutect2, varscan2
- MC1R | c.*397G>C | 3'UTR (SNP) | VAF 12/80 reads (15%) | catalogued as rs905746764; called by muse, mutect2, varscan2
- MOK | c.1182+38C>T | Intron (SNP) | VAF 52/378 reads (14%) | catalogued as rs758494850; called by muse, mutect2, varscan2
- PHGDH | c.290+47C>T | Intron (SNP) | VAF 16/141 reads (11%) | catalogued as rs746056443; called by mutect2, varscan2
- PPARGC1B | chr5:149730301 del C | 5'Flank (DEL) | VAF 22/79 reads (28%) | called by mutect2, pindel, varscan2
- TNRC18 | chr7:5428229 A>C | 5'Flank (SNP) | VAF 18/108 reads (17%) | catalogued as rs1434995006; called by muse, mutect2, varscan2
- ZNF805 | c.-12C>G | 5'UTR (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
